CCDI case PBBWAH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/8b4cb0ed-fde7-412f-a5e2-a5d160cebc5a

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: External ear; Age at diagnosis: 4.3 years (1,567 days).

Biospecimens (2 samples)
- Sample 0DIY5X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIY6A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
